Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9U6, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9U6-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Cervix biopsy:
Non-keratinizing invasive squamous cell carcinoma.

Addendum:

Angiolymphatic invasion not detected.

ICD O-3
Carcinoma, squamous cell
non-keratinizing NOS 8072/3
Site Cervix NOS 6839
JAW 3/7/14

Source: NCI Genomic Data Commons file 7e98c16f-a25c-4cc3-b59e-3b0d3994d7b0 (TCGA-VS-A9U6.BB78B2C7-E9AF-47D4-AAA2-354D1CFC2F76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).